Somatic mutation profile of tumor specimen TCGA-DV-A4VX-01A (aliquot TCGA-DV-A4VX-01A-11D-A25V-10) from TCGA case TCGA-DV-A4VX, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 59.3 years (21,670 days).
Specimen TCGA-DV-A4VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ab66d6e-5501-42f5-b90f-da8c84bf40a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-A4VX-10A (Blood Derived Normal), aliquot TCGA-DV-A4VX-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1c7109e-dda6-4e20-bd10-bb3c6a4db6e6

The open-access MAF lists 90 somatic variants for this specimen: 74 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 53, Silent 16, Frame Shift Del 8, Nonsense Mutation 5, Splice Site 3, Frame Shift Ins 3, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447754; called by muse, mutect2, varscan2
- ADGRE5 | c.1762A>T p.I588F (on ENST00000242786 / NM_078481.4; = p.I495F on NM_001784.5) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99660528; called by muse, mutect2, varscan2
- ALDH1L2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs1412359998, COSV99311333; called by muse, varscan2
- ATG7 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as COSV100608025; called by muse, mutect2, varscan2
- C18orf21 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV99321683; called by muse, mutect2, varscan2
- CACNA1A | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV64191388; called by muse, mutect2, varscan2
- CAPS2 | c.1469G>A p.W490* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100158294; called by muse, mutect2
- CATSPERD | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as rs779055195, COSV58464299; called by muse, mutect2, varscan2
- CD44 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99556027; called by muse, mutect2, varscan2
- CDH10 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs140810299; called by muse, mutect2, varscan2
- CDH12 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs371189490; called by muse, mutect2
- CELSR2 | c.3737T>A p.V1246E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99604770; called by muse, mutect2, varscan2
- CENPC | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs780441720, COSV99894454; called by muse, mutect2, varscan2
- CEP83 | c.1898T>A p.I633N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99313883; called by mutect2, varscan2
- CLDN19 | c.473+2T>C p.X158_splice | Splice Site (SNP) | VAF 85/198 reads (43%) | catalogued as COSV99591764; called by muse, mutect2, varscan2
- COL20A1 | c.2458A>G p.S820G | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.34); catalogued as COSV100491483; called by muse, mutect2, varscan2
- COL24A1 | c.2464-1G>C p.X822_splice | Splice Site (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100993613, COSV100994011; called by muse, mutect2, varscan2
- COL4A5 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 85/118 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0.125); catalogued as rs773883586, CM129357, COSV100089990; called by muse, mutect2, varscan2
- COL5A1 | c.3023C>T p.T1008M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199735010, COSV65667915; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- DERL1 | c.503del p.G168Afs*3 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | catalogued as COSV52365157; called by mutect2, pindel, varscan2
- DHCR24 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV100987848; called by muse, mutect2, varscan2
- DLGAP4 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs566349850, COSV100211625; called by muse, mutect2, varscan2
- DMTF1 | c.1118G>C p.S373T | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV100487522, COSV58687844; called by muse, mutect2, varscan2
- DOCK9 | c.3289C>G p.L1097V (on ENST00000376460 / NM_001366676.2; = p.L1098V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs749324182, COSV100241057; called by muse, mutect2, varscan2
- DSN1 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.046); catalogued as rs771230401, COSV101041115, COSV65518842; called by muse, mutect2, varscan2
- EFCAB5 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.012); catalogued as COSV100300777; called by muse, mutect2, varscan2
- FBN2 | c.8047G>C p.G2683R | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99329161; called by muse, mutect2
- FCRL1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs1156793592, COSV100839909; called by muse, mutect2
- GALNT13 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV101224250; called by muse, mutect2, varscan2
- GLB1L3 | c.1721T>G p.F574C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101345160; called by muse, mutect2, varscan2
- MC5R | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); catalogued as COSV100229173; called by muse, mutect2, varscan2
- MTMR11 | c.388G>C p.E130Q (on ENST00000439741 / NM_001145862.2; = p.E58Q on NM_181873.3) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100809315; called by muse, mutect2, varscan2
- NUP153 | c.3287C>T p.S1096L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs760850709, COSV50459409; called by muse, mutect2, varscan2
- OR5K2 | c.949T>C p.*317Rext*4 | Nonstop Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV101415986; called by muse, mutect2, varscan2
- OR5R1 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56572299, COSV56572699; called by muse, mutect2
- PCDHB13 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 126/470 reads (27%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.013); catalogued as COSV99507862; called by muse, mutect2, varscan2
- PHF14 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 33/118 reads (28%) | catalogued as COSV101301862; called by muse, mutect2
- PHF20L1 | c.627T>G p.F209L | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99622202; called by muse, mutect2, varscan2
- PHLPP2 | c.1028A>C p.N343T | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.119); catalogued as COSV62426496; called by muse, mutect2, varscan2
- PLCXD2 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); catalogued as COSV101210146; called by muse, mutect2, varscan2
- PPM1K | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV99901175; called by muse, mutect2, varscan2
- PPP1R15B | c.1855T>C p.C619R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.8); catalogued as COSV100916379; called by muse, mutect2, varscan2
- PRL | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100123236; called by muse, mutect2, varscan2
- PSME3 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.891); catalogued as COSV99513810; called by muse, mutect2, varscan2
- PTPRN2 | c.1478A>T p.E493V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101235374; called by muse, mutect2, varscan2
- RAPGEF1 | c.2875A>G p.T959A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.88); catalogued as COSV64697855; called by muse, mutect2, varscan2
- RNF150 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV60789165, COSV60795272; called by muse, mutect2, varscan2
- SAMD10 | c.285C>G p.Y95* | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV99412862; called by muse, mutect2, varscan2
- SEMA4D | c.2189C>A p.S730Y | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.201); catalogued as COSV100358834; called by muse, mutect2, varscan2
- SIGLEC8 | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367400, COSV100367412; called by muse, mutect2, varscan2
- SLC34A1 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100184125; called by muse, mutect2, varscan2
- SPEN | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005629; called by muse, mutect2, varscan2
- ST8SIA1 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99683549; called by muse, mutect2, varscan2
- STK3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101372662; called by muse, mutect2, varscan2
- SUPT6H | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV100112786; called by muse, mutect2, varscan2
- THEMIS | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV100965598; called by muse, mutect2, varscan2
- TYK2 | c.2998C>A p.L1000M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99315492; called by muse, mutect2, varscan2
- VHL | c.393C>A p.N131K | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1064794272, CM042502, CX073799, COSV56548229, COSV56549993; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- VWA3A | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as rs1249363653, COSV100241329; called by muse, mutect2, varscan2
- ZEB2 | c.3442T>A p.Y1148N | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as COSV100356946; called by muse, mutect2, varscan2
- ZNF155 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99525809; called by muse, mutect2, varscan2
- ACTL6A | c.383del p.N128Ifs*9 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, varscan2
- ARHGAP5 | c.645del p.F215Lfs*10 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- CARD6 | c.851dup p.V285Gfs*3 | Frame Shift Ins (INS) | VAF 54/102 reads (53%) | called by mutect2, pindel, varscan2
- FYB1 | c.367dup p.E123Gfs*25 | Frame Shift Ins (INS) | VAF 44/84 reads (52%) | called by mutect2, pindel, varscan2
- KDM5C | c.1211_1213dup p.F404_K405insI | In Frame Ins (INS) | VAF 69/115 reads (60%) | called by mutect2, pindel, varscan2
- KTN1 | c.547del p.T183Lfs*41 | Frame Shift Del (DEL) | VAF 60/126 reads (48%) | called by mutect2, pindel, varscan2
- RBP3 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETD2 | c.6887_6888del p.Y2296Lfs*72 | Frame Shift Del (DEL) | VAF 60/138 reads (43%) | called by pindel, varscan2
- SMC4 | c.3728del p.N1243Mfs*5 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by pindel, varscan2
- TRMT2B | c.1078_1082del p.L360Sfs*12 | Frame Shift Del (DEL) | VAF 22/37 reads (59%) | called by mutect2, pindel, varscan2
- XPO1 | c.861del p.F287Lfs*3 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- YAE1 | c.130-12_141del p.X44_splice | Splice Site (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3490dup p.S1164Ffs*57 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- ATXN2 | c.1389T>C p.D463= (on ENST00000550104; = p.D303= on NM_002973.4) | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV101112908; called by muse, mutect2, varscan2
- DGKI | c.336G>A p.K112= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1355268694, COSV99937375; called by muse, mutect2
- DYNC2H1 | c.6972T>C p.S2324= | Silent (SNP) | VAF 88/110 reads (80%) | catalogued as COSV100519815; called by muse, mutect2, varscan2
- ETAA1 | c.1377A>C p.A459= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99712957; called by muse, mutect2, varscan2
- FCAMR | c.342G>T p.L114= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100249768; called by muse, mutect2, varscan2
- HNRNPLL | c.492A>T p.G164= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV99696714; called by muse, mutect2, varscan2
- HRNR | c.5757A>G p.S1919= | Silent (SNP) | VAF 81/449 reads (18%) | catalogued as rs1197124833, COSV64256061; called by muse, mutect2, varscan2
- KCNT2 | c.2745A>G p.G915= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99656874; called by muse, mutect2, varscan2
- LYST | c.2238A>C p.A746= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV101090331; called by muse, mutect2, varscan2
- MORN1 | c.276G>A p.L92= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100088030; called by muse, mutect2, varscan2
- PSPC1 | c.1104A>G p.E368= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs772611694, COSV100142679; called by muse, mutect2, varscan2
- RCHY1 | c.30C>T p.A10= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV100185982; called by muse, mutect2, varscan2
- TTN | c.38448G>A p.K12816= (on ENST00000591111; = p.K5392= on NM_003319.4) | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs756061256, COSV100630748; called by muse, mutect2, varscan2
- UHRF1BP1 | c.630T>C p.I210= | Silent (SNP) | VAF 68/191 reads (36%) | catalogued as COSV99512495; called by muse, mutect2, varscan2
- WSCD2 | c.1554C>T p.F518= | Silent (SNP) | VAF 83/158 reads (53%) | catalogued as rs370666947, COSV99774293; called by muse, mutect2, varscan2
- ZNF33B | c.897A>G p.K299= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100847785; called by muse, mutect2, varscan2
